Somatic mutation profile of tumor specimen TCGA-2J-AAB9-01A (aliquot TCGA-2J-AAB9-01A-11D-A40W-08) from TCGA case TCGA-2J-AAB9, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 71.0 years (25,920 days).
Specimen TCGA-2J-AAB9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b952b63-a8c1-401f-994d-bb2ababede4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AAB9-10A (Blood Derived Normal), aliquot TCGA-2J-AAB9-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f75ab20-d224-4ffd-abbc-ded0e6b06740

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 28/358 reads (8%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2
- ABCB1 | c.734T>C p.L245S | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV99712442; called by muse, mutect2
- C1QTNF7 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 50/952 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.672); catalogued as COSV99765065; called by muse, mutect2
- CNTNAP4 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 21/420 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56683277; called by muse, mutect2
- CSE1L | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.372); catalogued as COSV99521901; called by muse, mutect2
- FHOD3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs960627486, COSV57173045, COSV99942301; called by muse, mutect2
- GRIP2 | c.2129G>A p.R710H (on ENST00000619221; = p.R613H on NM_001080423.4) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs566897826, COSV56122631; called by muse, mutect2
- KDM6A | c.1924-1G>T p.X642_splice | Splice Site (SNP) | VAF 10/174 reads (6%) | catalogued as COSV100937988, COSV65041733; called by muse, mutect2
- MED12L | c.5470G>A p.G1824S | Missense Mutation (SNP) | VAF 36/834 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1233484146, COSV56377412; called by muse, mutect2
- MYLK | c.5132C>T p.T1711M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374662467, COSV100658669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA3 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 23/534 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); catalogued as COSV63540347; called by muse, mutect2
- C1orf94 | c.1033C>T p.P345S (on ENST00000488417 / NM_001134734.2; = p.P155S on NM_032884.5) | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); called by muse, mutect2
- CCDC50 | c.1105G>A p.D369N (on ENST00000392455 / NM_178335.3; = p.D193N on NM_174908.4) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTL9 | c.600C>T p.H200= | Silent (SNP) | VAF 22/331 reads (7%) | catalogued as COSV61004826; called by muse, mutect2
- CARD6 | c.2907C>T p.S969= | Silent (SNP) | VAF 50/1292 reads (4%) | catalogued as COSV99620476; called by muse, mutect2
- EPB41L5 | c.177G>A p.L59= | Silent (SNP) | VAF 56/799 reads (7%) | catalogued as COSV99758434; called by muse, mutect2
- EVI2A | c.351T>C p.H117= | Silent (SNP) | VAF 34/607 reads (6%) | catalogued as rs773681381, COSV99907526; called by muse, mutect2
- FARSB | c.991C>T p.L331= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as COSV99918229; called by muse, mutect2
- GAREM1 | c.1833G>A p.P611= (on ENST00000269209 / NM_001242409.2; = p.P610= on NM_022751.3) | Silent (SNP) | VAF 21/299 reads (7%) | catalogued as rs765894192, COSV99330361; called by muse, mutect2
